Somatic mutation profile of tumor specimen HCM-CSHL-0382-C19-01A (aliquot HCM-CSHL-0382-C19-01A-11D-A78T-36) from HCMI case HCM-CSHL-0382-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 68.0 years (24,847 days).
Specimen HCM-CSHL-0382-C19-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2abbf6c-871e-43ee-b00e-742472d2cec6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0382-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0382-C19-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/439e8764-78b3-4b83-ae7e-187ff1320f9a

The open-access MAF lists 165 somatic variants for this specimen: 109 protein-altering or splice-affecting, 41 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 41, Nonsense Mutation 7, Intron 6, Frame Shift Del 4, RNA 3, Frame Shift Ins 3, 5'UTR 2, In Frame Del 2, Splice Region 2, 3'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1263G>A p.W421* | Nonsense Mutation (SNP) | VAF 17/156 reads (11%) | catalogued as rs1554080106, CM083583, CX1110728, COSV57320574, COSV57364239; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 24/209 reads (11%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 118/715 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, mutect2, varscan2
- TP53 | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 63/205 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567555667, COSV52680942, COSV52985275; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs113677156, COSV65405340; called by muse, mutect2, varscan2
- AGXT2 | c.560A>G p.N187S | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV51484995; called by muse, mutect2
- ATP7B | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs1425712013; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4186G>T p.D1396Y | Missense Mutation (SNP) | VAF 43/425 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63244314; called by muse, mutect2, varscan2
- C2orf81 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99292489; called by muse, mutect2, varscan2
- CA10 | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99563557; called by muse, mutect2
- CDR2 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs145347510; called by muse, mutect2
- CHRNA4 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as rs150336658; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CHST15 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 62/396 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1281580042, COSV99068214; called by muse, mutect2, varscan2
- CHTF18 | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 49/300 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs927638441; called by muse, mutect2, varscan2
- COL15A1 | c.4027C>T p.R1343* | Nonsense Mutation (SNP) | VAF 34/267 reads (13%) | catalogued as rs1450959518, COSV66640905; called by muse, mutect2, varscan2
- DHX37 | c.2635G>A p.G879R | Missense Mutation (SNP) | VAF 53/416 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148208268; called by muse, mutect2, varscan2
- DLG2 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs146095353, COSV104381829; called by muse, mutect2
- DUSP11 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 48/512 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs1307552596; called by muse, mutect2
- FLG | c.9593T>G p.V3198G | Missense Mutation (SNP) | VAF 82/680 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs143183339; called by muse, mutect2, varscan2
- FNBP4 | c.2908C>T p.R970W | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs773342165; called by muse, mutect2, varscan2
- GPHN | c.1690C>A p.R564S (on ENST00000315266 / NM_001377519.1; = p.R597S on NM_020806.5) | Missense Mutation (SNP) | VAF 63/426 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV104400759; called by muse, mutect2, varscan2
- GPR37 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as rs774806947, COSV58259643; called by muse, mutect2, varscan2
- GPRIN1 | c.2240G>A p.R747H | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1445549801, COSV56134983; called by muse, mutect2
- HYAL3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs377396269; called by muse, mutect2, varscan2
- ITIH1 | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs774566520; called by muse, mutect2, varscan2
- ITIH3 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.069); catalogued as rs765314854, COSV69649389; called by muse, mutect2, varscan2
- LCT | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1017501359, COSV51555251, COSV99928905; called by muse, mutect2, varscan2
- LRP8 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 88/609 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.313); catalogued as rs1216741308; called by muse, mutect2, varscan2
- MOGAT3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 50/372 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as rs139340331, COSV56175477; called by muse, mutect2, varscan2
- MYBPC1 | c.1715G>A p.R572Q (on ENST00000550270 / NM_206820.2; = p.R597Q on NM_002465.4) | Missense Mutation (SNP) | VAF 50/471 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs149018411, COSV62252673; called by muse, mutect2, varscan2
- OR8K5 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756900844, COSV57889897, COSV57889909; called by muse, mutect2, varscan2
- PCDHA7 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 134/490 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs782575776, COSV100971806, COSV65346027; called by muse, mutect2, varscan2
- PCDHGB5 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 76/874 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs756009874, COSV53966911; called by muse, mutect2
- PLN | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 65/423 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); catalogued as rs761056344, CM152289, COSV100682504, COSV62645794; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAB38 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760114172, COSV54712089; called by muse, mutect2, varscan2
- RAD21 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); catalogued as rs780692465, COSV52061251, COSV52061293; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAPGEF4 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV51389637; called by muse, mutect2, varscan2
- RING1 | c.767C>A p.P256Q | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.212); catalogued as rs1288256354; called by muse, mutect2, varscan2
- ROBO2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778332221, COSV59906905; called by muse, mutect2, varscan2
- SEC16A | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs1445008267; called by muse, mutect2, varscan2
- SLC16A14 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 27/157 reads (17%) | catalogued as COSV54621965; called by muse, mutect2, varscan2
- SMPDL3A | c.111A>G p.I37M | Missense Mutation (SNP) | VAF 59/459 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1234418516; called by muse, mutect2, varscan2
- SPTBN4 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 42/323 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.216); catalogued as rs763945874; called by muse, mutect2, varscan2
- SYTL4 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 62/487 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201221018, COSV52170730; called by muse, varscan2
- TBC1D17 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs117240064; called by muse, mutect2
- TBX20 | c.23A>G p.K8R | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as rs760680589; called by muse, mutect2
- TECRL | c.333C>T p.G111= | Splice Region (SNP) | VAF 17/119 reads (14%) | catalogued as rs535849187, COSV67085280; called by muse, mutect2, varscan2
- TECTA | c.3283C>T p.R1095C | Missense Mutation (SNP) | VAF 100/322 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as rs931887540; called by muse, mutect2, varscan2
- TNXB | c.5093C>T p.P1698L (on ENST00000647633; = p.P1451L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771493330; called by muse, mutect2, varscan2
- TOR2A | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1239249032; called by muse, mutect2, varscan2
- TRIB3 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 120/644 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs200611082, COSV53933040; called by muse, mutect2, varscan2
- TTLL7 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as rs868019143; called by muse, mutect2, varscan2
- ZNF470 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV57967824; called by muse, mutect2, varscan2
- ZNF577 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768421805, COSV56814925; called by muse, mutect2
- ZNF583 | c.864_865del p.R288Sfs*11 | Frame Shift Del (DEL) | VAF 21/213 reads (10%) | catalogued as rs759925007; called by pindel, varscan2
- ZNF791 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs765211548; called by muse, mutect2, varscan2
- ZNF835 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 53/614 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1309824359, COSV73379606, COSV73379622; called by muse, mutect2
- AKR1C2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD30B | c.4042_4043insC p.N1348Tfs*2 | Frame Shift Ins (INS) | VAF 10/82 reads (12%) | called by mutect2, varscan2
- APBA3 | c.598del p.Y200Tfs*64 | Frame Shift Del (DEL) | VAF 18/177 reads (10%) | called by mutect2, pindel, varscan2
- ARRDC5 | c.555G>T p.Q185H (on ENST00000381781; = p.Q171H on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ATP2B2 | c.1942_1944del p.K648del (on ENST00000352432; = p.K614del on NM_001683.5) | In Frame Del (DEL) | VAF 50/348 reads (14%) | called by pindel, varscan2
- C3orf22 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- CCDC15 | c.1980C>A p.D660E | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.116); called by muse, mutect2
- CNDP2 | c.903G>T p.K301N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CNTN1 | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 19/200 reads (10%) | called by muse, mutect2
- COL9A1 | c.1735C>A p.P579T | Missense Mutation (SNP) | VAF 41/360 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CYP2S1 | c.801C>G p.D267E | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DDI2 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNAH5 | c.13149G>A p.M4383I | Missense Mutation (SNP) | VAF 86/515 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- DPYS | c.1235+1G>T p.X412_splice | Splice Site (SNP) | VAF 47/402 reads (12%) | called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2026del p.Q676Rfs*3 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | called by mutect2, pindel, varscan2
- EPHA7 | c.932A>C p.E311A | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- FRMD4A | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- GABRA1 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- GLI1 | c.627T>C p.D209= | Splice Region (SNP) | VAF 49/198 reads (25%) | called by muse, mutect2, varscan2
- GRID2 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.168); called by muse, mutect2
- INPP4B | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.088); called by muse, mutect2
- IRS1 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 90/384 reads (23%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MED14 | c.2944G>A p.D982N | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NCAM2 | c.806G>C p.R269T | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- NID2 | c.2372G>T p.G791V | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLGN4X | c.1567G>C p.V523L | Missense Mutation (SNP) | VAF 69/602 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- NOMO1 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 30/323 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NT5DC3 | c.1091T>C p.I364T | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- OASL | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 60/491 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- OSBPL6 | c.365C>A p.P122Q | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); called by muse, mutect2
- OVCH1 | c.2894G>T p.S965I | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- PARG | c.1954G>T p.E652* | Nonsense Mutation (SNP) | VAF 30/217 reads (14%) | called by muse, mutect2, varscan2
- PIGG | c.2444C>T p.P815L (on ENST00000453061 / NM_001127178.3; = p.P807L on NM_017733.4) | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2
- POLR1A | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- QTRT1 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RESF1 | c.3897del p.H1300Tfs*3 | Frame Shift Del (DEL) | VAF 20/128 reads (16%) | called by mutect2, pindel, varscan2
- RNF225 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 23/626 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.413); called by muse, mutect2
- RPL36 | c.111dup p.K38Qfs*79 | Frame Shift Ins (INS) | VAF 45/380 reads (12%) | called by mutect2, pindel, varscan2
- SEC63 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2
- SHROOM1 | c.356_367del p.A119_A122del | In Frame Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- SLCO5A1 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SND1 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- SPACA7 | c.283A>G p.N95D | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.767); called by muse, mutect2
- SPATA31E1 | c.2680T>G p.F894V | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SUPT20HL1 | c.425T>A p.V142D | Missense Mutation (SNP) | VAF 17/265 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SYTL3 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); called by muse, mutect2
- TMEM94 | c.1001G>T p.W334L | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TNR | c.2624T>C p.V875A | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- TTN | c.69175C>A p.P23059T (on ENST00000591111; = p.P15635T on NM_003319.4) | Missense Mutation (SNP) | VAF 41/176 reads (23%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VKORC1L1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ZIK1 | c.738dup p.A247Sfs*25 | Frame Shift Ins (INS) | VAF 34/290 reads (12%) | called by mutect2, pindel, varscan2
- ZNF99 | c.943T>C p.C315R | Missense Mutation (SNP) | VAF 44/542 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCA13 | c.10902C>A p.I3634= | Silent (SNP) | VAF 34/444 reads (8%) | catalogued as COSV71293577; called by muse, mutect2
- ALDH1L2 | c.2226C>T p.D742= | Silent (SNP) | VAF 24/226 reads (11%) | catalogued as rs781613297; called by muse, mutect2, varscan2
- ARAP1 | c.1329C>T p.R443= (on ENST00000393609 / NM_001040118.2; = p.R198= on NM_015242.4) | Silent (SNP) | VAF 82/560 reads (15%) | catalogued as rs975746779, COSV61993548; called by muse, mutect2, varscan2
- B3GALNT2 | c.666A>T p.T222= | Silent (SNP) | VAF 37/245 reads (15%) | called by muse, mutect2, varscan2
- CACNB2 | c.909G>T p.A303= (on ENST00000324631 / NM_201596.3; = p.A248= on NM_000724.4) | Silent (SNP) | VAF 47/340 reads (14%) | called by muse, mutect2, varscan2
- CFAP74 | c.3492C>T p.H1164= | Silent (SNP) | VAF 32/149 reads (21%) | catalogued as rs1330941752; called by muse, mutect2, varscan2
- CNTN6 | c.1134G>T p.V378= | Silent (SNP) | VAF 18/171 reads (11%) | called by muse, mutect2, varscan2
- DLGAP4 | c.2931C>T p.S977= (on ENST00000339266 / NM_001365621.1; = p.S974= on NM_014902.6) | Silent (SNP) | VAF 77/407 reads (19%) | catalogued as rs150199875; called by muse, mutect2, varscan2
- DPP7 | c.279G>A p.E93= | Silent (SNP) | VAF 66/410 reads (16%) | catalogued as rs1361750987; called by muse, varscan2
- EFCAB8 | c.1995C>T p.T665= | Silent (SNP) | VAF 34/600 reads (6%) | catalogued as rs539746872; called by muse, mutect2
- EPHA6 | c.924G>A p.L308= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as COSV101064308, COSV67556607; called by muse, mutect2, varscan2
- EPPK1 | c.2377C>T p.L793= | Silent (SNP) | VAF 36/275 reads (13%) | catalogued as COSV73261057; called by muse, mutect2, varscan2
- ERAP2 | c.2322C>T p.F774= | Silent (SNP) | VAF 29/144 reads (20%) | called by muse, mutect2, varscan2
- FANCG | c.390C>T p.C130= | Silent (SNP) | VAF 110/716 reads (15%) | catalogued as rs1489760268; called by muse, mutect2, varscan2
- GRHPR | c.525C>T p.F175= | Silent (SNP) | VAF 61/487 reads (13%) | catalogued as rs749885934, COSV58945798; called by muse, mutect2, varscan2
- IGHV3-72 | c.111G>T p.L37= | Silent (SNP) | VAF 55/437 reads (13%) | called by muse, mutect2, varscan2
- IGKV3D-20 | c.87C>T p.A29= | Silent (SNP) | VAF 52/631 reads (8%) | called by muse, mutect2
- KRT1 | c.1920C>A p.S640= | Silent (SNP) | VAF 61/544 reads (11%) | catalogued as COSV52868110; called by muse, mutect2, varscan2
- LRRC23 | c.408G>T p.L136= | Silent (SNP) | VAF 46/488 reads (9%) | called by muse, mutect2
- MAGEB6B | c.918G>A p.E306= | Silent (SNP) | VAF 40/359 reads (11%) | called by muse, mutect2, varscan2
- MAP2K2 | c.903C>T p.P301= | Silent (SNP) | VAF 46/303 reads (15%) | catalogued as rs560316877; ClinVar: likely benign; called by muse, mutect2, varscan2
- MTUS2 | c.1683C>T p.F561= | Silent (SNP) | VAF 28/215 reads (13%) | catalogued as rs376749747; called by muse, mutect2, varscan2
- MYH11 | c.1908G>A p.E636= | Silent (SNP) | VAF 14/468 reads (3%) | catalogued as rs1312174913; called by muse, mutect2
- NIBAN3 | c.1743G>A p.L581= | Silent (SNP) | VAF 35/256 reads (14%) | called by muse, mutect2, varscan2
- OSMR | c.1962T>G p.P654= | Silent (SNP) | VAF 50/354 reads (14%) | called by muse, mutect2, varscan2
- P2RY13 | c.511T>C p.L171= | Silent (SNP) | VAF 39/329 reads (12%) | called by muse, mutect2, varscan2
- PCARE | c.2256C>T p.D752= | Silent (SNP) | VAF 59/201 reads (29%) | catalogued as rs375644198; called by muse, mutect2, varscan2
- PLA2R1 | c.175C>T p.L59= | Silent (SNP) | VAF 45/196 reads (23%) | catalogued as rs1165211630; called by muse, mutect2, varscan2
- RIMS2 | c.3798C>T p.R1266= | Silent (SNP) | VAF 23/185 reads (12%) | catalogued as rs1287561799; called by muse, mutect2, varscan2
- RYR2 | c.12084G>A p.S4028= | Silent (SNP) | VAF 25/242 reads (10%) | catalogued as rs751821960, COSV63682739, COSV63702754; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEL1L3 | c.468C>T p.Y156= | Silent (SNP) | VAF 23/208 reads (11%) | called by muse, mutect2, varscan2
- SLC17A9 | c.1101C>T p.C367= | Silent (SNP) | VAF 34/214 reads (16%) | catalogued as rs778254246; called by muse, mutect2, varscan2
- SLC5A2 | c.1152G>A p.A384= | Silent (SNP) | VAF 68/616 reads (11%) | catalogued as CD035009, COSV57891854; called by muse, mutect2, varscan2
- SPHK2 | c.1548C>T p.P516= | Silent (SNP) | VAF 19/155 reads (12%) | catalogued as rs1451837747, COSV55335124; called by muse, mutect2, varscan2
- SRPK3 | c.465C>T p.V155= | Silent (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
- STIP1 | c.42C>T p.A14= | Silent (SNP) | VAF 17/286 reads (6%) | catalogued as rs777596225; called by muse, mutect2
- TEX22 | c.300C>G p.A100= | Silent (SNP) | VAF 29/281 reads (10%) | called by muse, mutect2, varscan2
- TNR | c.3234C>T p.T1078= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as rs200777712, COSV54902159; called by muse, mutect2, varscan2
- VPS53 | c.1002C>T p.T334= (on ENST00000571805 / NM_001366253.2; = p.T305= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2
- ZAP70 | c.60C>T p.A20= | Silent (SNP) | VAF 37/253 reads (15%) | catalogued as rs1204892323; called by muse, mutect2, varscan2
- ZBTB10 | c.588C>A p.G196= | Silent (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- AC004080.3 | c.11-4490C>T | Intron (SNP) | VAF 126/757 reads (17%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-8591G>A | Intron (SNP) | VAF 20/186 reads (11%) | catalogued as rs781803344, COSV101595483; called by muse, mutect2
- DNAJA4 | chr15:78264257 C>T | 5'Flank (SNP) | VAF 15/50 reads (30%) | catalogued as rs1315129556; called by muse, mutect2, varscan2
- FAM149A | c.1602+301C>T | Intron (SNP) | VAF 18/190 reads (9%) | catalogued as rs563612662; called by muse, mutect2, varscan2
- MRPL10 | c.52+40C>T | Intron (SNP) | VAF 48/347 reads (14%) | catalogued as rs1367693303; called by muse, mutect2, varscan2
- MTR | c.-180G>T | 5'UTR (SNP) | VAF 11/304 reads (4%) | called by muse, mutect2
- MYO1B | c.2557-10_2557-8del | Intron (DEL) | VAF 17/117 reads (15%) | called by pindel, varscan2
- NEUROD1 | c.-6C>T | 5'UTR (SNP) | VAF 21/200 reads (11%) | called by muse, mutect2
- NFATC2 | c.*110C>T | 3'UTR (SNP) | VAF 156/425 reads (37%) | catalogued as rs542710098, COSV65360154; called by muse, mutect2, varscan2
- SEPTIN9 | c.*495G>A | 3'UTR (SNP) | VAF 30/251 reads (12%) | catalogued as rs773245212; called by muse, mutect2, varscan2
- SNORD114-1 | n.72A>C | RNA (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- SSPOP | n.6964G>A | RNA (SNP) | VAF 60/478 reads (13%) | catalogued as rs569350279, COSV50487248; called by muse, mutect2, varscan2
- STAT1 | c.-1-376A>T | Intron (SNP) | VAF 17/181 reads (9%) | called by muse, mutect2
- TP73-AS1 | n.1549G>A | RNA (SNP) | VAF 53/392 reads (14%) | catalogued as rs562084723; called by muse, mutect2, varscan2
- ZNF625 | chr19:12142506 C>A | 3'Flank (SNP) | VAF 36/207 reads (17%) | called by muse, mutect2, varscan2
